Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A48G, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A48G-01A (Primary Tumor).

[page 1 of 3]
Sex: Female
D.O.B.:
MRN #
Ref Phy

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right pelvic lymph node, excision:
One lymph node, negative for metastatic disease.
Frozen section diagnosis confirmed.
- B, C: Uterus with bilateral adnexa, hysterectomy with bilateral salpingo-oophorectomy.
Tumor histologic type: Leiomyosarcoma.
Location: Tumor involves the left paraovarian tissue as well as uterus.
Size: 7.2 x 5.8 x 2.2 cm adjacent to ovary, 13.5 x 9.5 x 8.7 cm within uterus.
Lymphovascular space invasion not identified.
Surgical margin status: Tumor extends throughout the myometrium into the serosal space and focally into the left parametrial tissue.
Other: Portions of residual left ovarian tissue and fallopian tube identified.
Right ovary and fallopian tube present with hysterectomy, uninvolved by tumor.
The tumor extends into cervical tissue.
pTNM Stage: pT2b NO (FIGO IIV).
- D. Upper vagina, biopsy:
Infiltrative tumor present throughout soft tissue.
- E. Left pelvic lymph nodes, excision:
Three lymph nodes, negative for metastatic disease.
- F. Left parametrium, biopsy:
Infiltrative tumor present within soft tissue.
- G. Cervix, excision:
Negative for tumor.
- H. Uterine tumor, biopsy:
Infiltrative tumor.
- I. Left pelvic lymph nodes, excision:
Two lymph nodes, negative for metastatic disease.
- J. Right pelvic lymph nodes, excision:
Six lymph nodes, negative for metastatic disease.
- K. Right periaortic lymph nodes, excision:
Three lymph nodes, negative for metastatic disease.
- L. Left periaortic lymph nodes, excision:
Four lymph nodes, negative for metastatic disease.
- M. Omentum, excision:
Negative for tumor.

1CD-0-3

leiomyosarcoma, NOS 8890/3

Site: uterus, NOS C55.9

hw
7/26/12

Electronic Signature:

COMMENTS:

Appropriately controlled immunohistochemical stains performed on blocks B2 and C5 show the following results:

Smooth Muscle Actin: Focally weakly positive in tumor.
Desmin: Strongly positive in tumor.
Caldesmon: Strongly positive in tumor.

[page 2 of 3]
Inhibin: Negative in tumor.
Calretinin: Negative in tumor.
Vimentin: Negative in tumor.
S100: Negative in tumor.
Pancytokeratin: Negative in tumor.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right pelvic lymph node frozen section
- B. Left tube and ovary frozen section
- C. Uterus and right tube and ovary frozen section
- D. Upper vagina
- E. Left pelvic lymph node
- F. Left parametrium
- G. Cervix
- H. Uterine tumor
- I. Left pelvic lymph node
- J. Right pelvic lymph nodes
- K. Right periaortic lymph node
- L. Left periaortic lymph node
- M. Omentum

SPECIMEN DATA

GROSS DESCRIPTION:

A. Part A received labeled and #1 is a 1.7 x 1.5 x 0.3 cm irregular tan soft tissue consistent with probable lymph node with attached adipose tissue which is submitted in toto for frozen section. The frozen section residue is submitted in one cassette labeled

B. Part B received labeled and #2 - Left tube and ovary frozen section is a 7.2 x 5.8 x 2.2 cm aggregate of gray-white to tan-pink firm tissue and yellow adipose tissue. The specimen cannot be oriented. The cut surface of the tissues consist of gray-white-tan soft tissue. There is a minimal amount of residual tan-pink ovarian stroma with gray-white corporal albicans. Attached to one of the tissues is a 3.3 x 0.5 cm fimbriated fallopian tube with a tan serosa with two paratubal cysts averaging 0.2 cm in greatest dimension and a pinpoint lumen. The specimen is serially sectioned and representative sections are submitted for frozen section. The frozen section residue is submitted in block 1. Additional representative sections are submitted in blocks 2-6 labeled Also received in the same container is a green and yellow cassette labeled for genomic research study.

C. Part C received labeled and #3 - Uterus, right tube and ovary is a 567 gram previously opened hysterectomy specimen consisting of an 11.7 x 10.5 x 7.2 cm uterine body and an attached 3.5 x 2.7 x 2.5 cm cervix. The right ovary and fallopian tube are attached to the cornu.

The serosal is smooth and tan-pink. The ectocervix is smooth and gray-white to pink. The os cannot be appreciated. The endocervical canal is tan and 2.8 cm in length. The endometrial cavity cannot be appreciated. There is a 13.5 x 9.5 x 8.7 cm lobulated to polypoid, gray-white to tan-yellow mass which diffusely involves the uterine body and extends to the cervix. The cut surface of the mass consists of focally hemorrhagic lobulated gray-white soft tissue. The mass diffusely involves the underlying myometrium, extending through the serosa, with a depth of 4.5 cm. The mass appears to involve the left parametrium.

No obvious uninvolved endometrium is identified. There is a minimal amount of residual tan-pink trabeculated myometrium.

The 2.1 x 1.1 x 0.8 cm right ovary has a lobulated tan-pink outer surface. The cut surface is tan with gray-white corpora albicans. The attached 4.8 x 0.5 cm fimbriated right fallopian tube has a red-brown serosa with multiple paratubal cysts averaging 0.1 cm in greatest dimension and a pinpoint lumen.

The specimen is inked serially sectioned and representative sections are submitted for frozen section and the frozen residue is submitted in block 1. Additional representative sections are submitted as labeled: Block 2. Anterior cervix; Block 3. Posterior cervix; Block 4. Anterior lower uterine segment; Block 5. Posterior lower uterine segment; Blocks 6 and 7. Anterior full-thickness mass, bisected; Blocks 8 and 9. Posterior full-thickness mass, bisected; Block 10. Mass; Block 11. Left parametrium; Block 12. Right parametrium; Block 13. Right ovary and fallopian tube. The blocks are labeled Also received in the same container is a blue cassette labeled for genomic research study.

D. Part D received in formalin labeled and #4 - Upper vagina is a 5.5 x 3.8 x 2.1 cm irregular shaggy tan-yellow soft tissue which is partially surfaced by a gray-white to tan mucosa. The cut surface consists of a 3.5 x 2.4 x 1.7 cm ill-defined gray-white to red area. The specimen is inked, serially sectioned and representative sections are submitted in blocks 1-3 labeled

E. Part E received in formalin labeled and #5 - Left pelvic lymph node are two irregular fibroadipose tissues measuring 2.8 x 1.4 x 0.5 cm

[page 3 of 3]
and 3.7 x 2.1 x 1.0 cm. The tissues are sectioned to reveal three irregular tan-yellow firm tissues consistent with probable lymph node ranging from 1.5 x 1.3 x 0.4 cm to 3.7 x 1.2 x 0.5 cm. Representative sections are submitted to include the lymph nodes in their entirety as labeled: Blocks 1-3. One lymph node bisected in each. The blocks labeled

F. Part F received in formalin labeled and #6 - Left parametrium is a 7.6 x 7.3 x 1.5 cm aggregate of tan-yellow to red soft tissue. The cut surface of the tissue consists of hemorrhagic gray-white soft tissue. The specimen is serially sectioned and representative sections are submitted in one cassette labeled

G. Part G received in formalin labeled and #7 - Cervix is a 3.5 x 1.8 x 1.4 cm irregular shaggy tan soft tissue which is partially surfaced by a gray-white to tan mucosa. The orientation of the specimen is not completely obvious. The specimen is serially sectioned and representative sections are submitted in blocks 1 and 2 labeled

H. Part H received in formalin labeled and #8 - Uterine tumor is a 4.8 x 3.1 x 1.9 cm irregular tan-red to green soft tissue. The cut surface consists of hemorrhagic white soft tissue. The specimen is serially sectioned and a representative section is submitted in one cassette labeled

I. Part I received in formalin labeled and #9 - Left pelvic lymph node is a 3.4 x 2.6 x 0.6 cm aggregate of fibroadipose tissue bearing two tan-red firm tissues consistent with probable lymph node measuring 0.8 x 0.7 x 0.4 cm and 1.5 x 1.1 x 0.4 cm. The specimen is sectioned and submitted in its entirety as labeled: Blocks 1 and 2. One lymph node bisected in each; Block 3. Remainder of tissue; The blocks are labeled

J. Part J received in formalin labeled and #10 - Right pelvic lymph node is a 5.2 x 3.5 x 0.8 cm aggregate of fibroadipose tissue bearing multiple tan-yellow firm tissues consistent with probable lymph node ranging from 0.5 x 0.4 x 0.2 cm to 2.5 x 2.2 x 0.7 cm. The cut surface of the largest lymph node is pink-white consistent with probably positive lymph node. The specimen is sectioned and representative sections are submitted as labeled: Block 1. Two whole probable lymph nodes; Block 2. One whole probable lymph node; Blocks 3-5. One lymph node bisected in each; Block 6. Representative section of probable positive lymph node. The blocks are labeled

K. Part K received in formalin labeled and #11 - Right paraortic lymph node is a 4.1 x 2.6 x 0.7 cm irregular fibroadipose tissue bearing multiple tan-yellow firm tissues consistent with probable lymph node ranging from 0.7 x 0.5 x 0.3 cm to 1.8 x 0.8 x 0.5 cm. The specimen is sectioned and representative sections are submitted to include the lymph nodes in their entirety as labeled: Blocks 1-3. One lymph node bisected in each. The blocks are labeled

L. Part L received in formalin labeled and #12 - Left paraortic lymph node is a 2.8 x 2.4 x 0.7 cm aggregate of fibroadipose tissue bearing four irregular tan-yellow firm tissues consistent with probable lymph node ranging from 0.3 x 0.2 x 0.2 cm to 1.5 x 0.9 x 0.4 cm. The specimen is sectioned and representative sections are submitted to include the lymph nodes in their entirety as labeled: Block 1. Two whole probable lymph nodes; Blocks 2 and 3. One lymph node bisected in each; The blocks are labeled

M. Part M received in formalin labeled and #13 Omentum is a 44.5 x 15.3 x 1.3 cm irregular fibroadipose tissue consistent with omentum. The cut surface consists of predominantly yellow lobulated adipose tissue with a scant amount of gray-white fibrous tissue. No lesions are identified. The specimen is serially sectioned and representative sections are submitted in blocks 1-4 labeled

9/30/12

Source: NCI Genomic Data Commons file 935fdd35-3abd-4562-958c-bdb2542a6d0f (TCGA-FX-A48G.B2704838-101C-4675-AD88-AFA59C6B6590.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).